Gene-level copy-number profile of tumor specimen TCGA-P5-A72U-01A from TCGA case TCGA-P5-A72U, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 71.2 years (26,002 days).
Specimen TCGA-P5-A72U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.590563a8-91cb-423d-a5ad-15e2ab47aeba.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P5-A72U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c34a568a-02db-49d4-8bb3-60d4f8dad508

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 5; copy number 2: 4,420; copy number 3: 279; copy number 4: 48,700; copy number 5: 175; copy number 6: 6,047; copy number 7: 3; copy number 9: 9; copy number 11: 62; copy number 28: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P5-A72U-01A-31D-A32A-01): tumor purity 0.46, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:41,265,339–41,271,835, 2 genes: KRTAP9-6, KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 120 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,190,824–201,228,952, 2 genes, copy number 11 (within-gene range 4–11): IGFN1, AC103925.1.
- chr6:170,535,120–170,738,536, 9 genes, copy number 9: PSMB1, TBP, PDCD2, AL031259.1, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr12:57,529,633–59,130,875, 49 genes, copy number 28 (within-gene range 4–28): DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1.
- chr17:56,914,186–58,557,799, 60 genes, copy number 11: AC015912.3, COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2, MSI2, AC091181.1, AC015883.1, AC007431.2, AC007431.3, AC007431.1, RN7SL449P, RNU7-134P, CCDC182, AC015845.2, RN7SKP94, MRPS23, CUEDC1, AC015845.1, AC015813.4, VEZF1, AC015813.7, AC015813.2, AC015813.1, SRSF1, AC015813.5, AC015813.8, AC015813.3, DYNLL2, AC015813.6, OR4D1, MSX2P1, OR4D2, EPX, AC005962.1, MKS1, LPO, AC005962.2, AC004687.3, MPO, TSPOAP1, TSPOAP1-AS1, AC004687.1, MIR142, MIR4736, SUPT4H1, AC004687.2, RNF43, HSF5, SETP3, MTMR4, SEPTIN4-AS1, SEPTIN4.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
